Somatic mutation profile of tumor specimen TCGA-W6-AA0T-01A (aliquot TCGA-W6-AA0T-01A-31D-A46P-09) from TCGA case TCGA-W6-AA0T, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.0 years (23,004 days).
Specimen TCGA-W6-AA0T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd0774b8-d75c-4fc8-9601-f24082556f12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W6-AA0T-10A (Blood Derived Normal), aliquot TCGA-W6-AA0T-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09d5e102-bab3-439f-a37d-9fa5fcffafd1

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6700C>T p.Q2234* (on ENST00000358273 / NM_001042492.3; = p.Q2213* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as rs1567617727, COSV62219556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV56238890; called by mutect2, varscan2
- CACNA1F | c.2884A>T p.I962F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV59905928; called by muse, mutect2, varscan2
- CLEC1B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753263519, COSV53726856; called by muse, mutect2, varscan2
- DNAH8 | c.12947C>T p.S4316L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765766734, COSV59443932; called by mutect2, varscan2
- FGF6 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs373568166; called by muse, mutect2, varscan2
- MID1IP1 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV61230993; called by muse, mutect2, varscan2
- NCBP3 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.182); catalogued as rs566972085, COSV50106763; called by muse, mutect2, varscan2
- NID1 | c.639C>A p.N213K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1450473403, COSV51625978; called by muse, varscan2
- OGFR | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1374053033; called by muse, mutect2, varscan2
- PRKD2 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs761575561; called by muse, mutect2, varscan2
- SCAF1 | c.2352_2369del p.D785_R790del | In Frame Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs1442561622; called by mutect2, varscan2
- SDAD1 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1343297573; called by muse, mutect2, varscan2
- ZNF366 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs778281671, COSV59216893; called by muse, mutect2, varscan2
- ADRM1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- B4GALT7 | c.476T>C p.I159T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2
- CAD | c.4834_4842del p.I1612_H1614del | In Frame Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- DLGAP5 | c.809C>A p.T270N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by mutect2, varscan2
- ELF3 | c.764_765del p.K255Rfs*45 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- GPR50 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HIVEP1 | c.7703C>T p.A2568V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.039); called by muse, mutect2
- HSFX1 | c.65A>G p.H22R | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.014); called by muse, varscan2
- NSF | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by mutect2, varscan2
- NSRP1 | c.174C>T p.T58= | Splice Region (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- OSBPL8 | c.2135C>G p.A712G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- PLK1 | c.968dup p.R324Kfs*22 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- SPATS2 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.104); called by mutect2, varscan2
- TMEM260 | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- TNXB | c.7813A>G p.I2605V (on ENST00000647633; = p.I2358V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TUBB2B | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- UBE2M | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF486 | c.-5_30+5del | Splice Site (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel
- CALN1 | c.105C>T p.P35= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as rs1285790616; called by muse, mutect2
- GPX8 | c.606C>A p.I202= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- HAUS4 | c.132C>A p.L44= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- HMCN1 | c.6420C>T p.D2140= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1413433754, COSV54893978, COSV54936825; called by muse, mutect2
- MAGEE1 | c.1704C>A p.P568= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV63911221; called by muse, mutect2, varscan2
- MUC20 | c.2112G>T p.L704= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- NYAP1 | c.2097A>T p.G699= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, varscan2
- PCARE | c.1329C>T p.I443= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV59053168; called by muse, mutect2, varscan2
- TAF2 | c.1269G>A p.E423= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV65417082; called by muse, mutect2, varscan2
- USP6NL | c.2421C>T p.P807= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1338434512; called by muse, mutect2, varscan2
- ZAN | c.8310G>T p.V2770= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV61816464; called by muse, varscan2
